Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A901, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A901-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Patient Name:

Address:

Gender:

DOB:

F

Age:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession:

Taken:

Received:

Reported:

Physician(s):

M.D.

M.D.

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, KERATINIZING CM IN GREATEST DIMENSION
- SQUAMOUS CELL CARCINOMA INVADERS TO A DEPTH OF 1.5 CM (TOTAL WALL THICKNESS)
- EXTENSIVE LYMPHVASCULAR SPACE INVASION IS PRESENT
- SEVERE DYSPLASIA (CIN III) IS PRESENT ADJACENT TO INVASIVE CARCINOMA

VAGINA, RADICAL HYSTERECTOMY

- INVASIVE SQUAMOUS CELL CARCINOMA IS PRESENT LESS THAN 0.2 MM FROM THE VAG CUFF MARGIN (12 TO 3 O'CLOCK)
- EXTENSIVE LYMPHVASCULAR SPACE INVASION IS PRESENT
- TUMOR IS PRESENT IN LYMPHVASCULAR SPACES AT 9 TO 12 O'CLOCK MARGIN
- EXTENSIVE SEVERE DYSPLASIA (VAIN III), INVOLVING MARGIN

VAGINA, LEFT MARGIN, SEPARATE BIOPSY

- INVASIVE SQUAMOUS CELL CARCINOMA
- EXTENSIVE LYMPHVASCULAR SPACE INVASION
- SEVERE DYSPLASIA (VAIN III)

PARAMETRIAL SOFT TISSUE, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED

LYMPH NODE, PARAMETRIAL SOFT TISSUE, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- INVASIVE SQUAMOUS CELL CARCINOMA INVOLVING POSTERIOR LOWER UTERINE SEG
- PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- INVASIVE SQUAMOUS CELL CARCINOMA INVOLVING POSTERIOR LOWER UTERINE SEG
- FOCAL ADENOMYOSIS

UTERUS, SEROSA, RADICAL HYSTERECTOMY

- SUBSEROSAL LEIOMYOMA, 0.7 CM

ICD-O-3

Carcinoma, squamous cell keratinizing NOS 8071/3

Site: Cervix NOS C53.9

QAD 1/21/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

LYMPH NODES, RIGHT PELVIC, EXCISION
- METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE OF SEVEN LYMPH NODES (1/7)

LYMPH NODES, LEFT PELVIC, EXCISION
- METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE OF NINE LYMPH NODES (1/9)

LYMPH NODES, RIGHT PERIAORTIC, EXCISION
- NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)

"LYMPH NODES," LEFT PERIAORTIC, EXCISION
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED
- NO LYMPH NODES IDENTIFIED (SPECIMEN ENTIRELY SUBMITTED)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis).

M.D.

M.I.

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [redacted] year old woman with cervical carcinoma. Operative procedure: Radical hysterectomy and lymph node dissection.

Specimen(s) Received:

- A: UTERUS & CERVIX
- B: LYMPH NODE RIGHT PELVIC
- C: LYMPH NODE LEFT PELVIC
- D: LYMPH NODE RIGHT PERIAORTIC
- E: LYMPH NODE LEFT PERIAORTIC
- F: LEFT VAGINA MARGIN

Gross Description

Received are six formalin-filled containers, each labeled with the patient's name. The first container is labeled "uterus and cervix." It contains a uterus with attached cervix, vaginal cuff and parametrial soft tissue. The uterus weighs 8 grams and measures 8 cm from fundus to ectocervix x 6.5 cm from cornu to cornu x 2 cm from anterior to posterior. The attached right and left parametrial soft tissues measure 4 x 3 x 1 cm and 4 x 2 x 1 cm, respectively. The right and posterior vaginal cuffs measure 4 by up to 1.5 cm and 4 x 1.5 cm, respectively. The ectocervix measures 1 cm with a mucosal surgical defect in the anterior cervix, measuring 1 cm in greatest dimension, and an ulcerated granular base in the posterior ectocervix, measuring 2 x 1.5 x 0.6 cm. The soft tissue and resection margin are inked black. The endocervical canal measures 3 cm in length x 0.6 cm in diameter, and is lined by a grey-tan granular mucosa. Part of the endocervical canal is occupied by a cervical tumor. The cervical mass shows grey-yellow, firm and vaguely lobulated cut surfaces without necrosis or hemorrhage and measures 3.7 x 3.1 cm in greatest dimension. The tumor invades to a depth of 1.6 cm in the total wall thickness of 2 cm. The tumor involves the posterior vaginal cuff and the parametrial soft tissue. The endometrial cavity measures 3 cm from fundus to the posterior vaginal cuff and the parametrial soft tissue. The endometrial cavity is lined by a tan and grey mucosa. The endometrial and myometrium of the lower uterine segment of the uterus is involved by cervical carcinoma grossly. The posterior vaginal cuff shows granular mucosa measuring 3 x 0.7 cm, adjacent to the cervical tumor. The anterior vaginal cuff has a 1.1 x 0.7 cm area of granular mucosa in the 12 to 6 o'clock area. The serosa of the posterior uterus has a 0.7 cm in greatest dimension nodule with white, firm, whorled and circumscribed cut surfaces. There are two separate serosal grey-yellow areas measuring 0.2 cm and 0.3 cm. Sectioning of the myometrium shows unremarkable cut surfaces. Labeled A1 to A3 - sections from posterior vaginal cuff to the endometrium; A8 - posterior vaginal cuff with adjacent tumor in the 3 to 6 o'clock quadrant; A9 to A16 - tumor and adjacent parametrial soft tissue; A17 and A18 - left upper parametrial soft tissue; A19 - left lower parametrial soft tissue; A20 - posterior tumor with serosa; A21 to A24 - right posterior parametrial soft tissue; A25 to A26 - right anterior parametrial soft tissue; A27 and A28 - sections from anterior vaginal cuff to the endometrium.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

A29 to A32 - anterior 12 to 3 o'clock quadrant, vaginal cuff with adjacent tumor; A33 - posterior 6 to 9 o'clock cuff; A34 - anterior, at 9 to 12 o'clock vaginal shave margin; A35 - grey-serosal areas; A36 - serosal nodules

The second container is labeled "right pelvic nodes." It contains multiple fragments of fibrofatty tissue measuring 2 cm in aggregate. Multiple lymph nodes are dissected out, measuring from 0.3 cm to 1.2 cm in greatest dimension. Sectioning of these lymph nodes shows homogeneous grey-white cut surfaces in one lymph node, which is suspicious for involvement by tumor. Labeled B1 to B3 - lymph nodes. Jar 1.

The third container is labeled "left pelvic nodes." It contains multiple fragments of fibrofatty tissue measuring 2 cm in aggregate. Multiple putative lymph nodes are dissected out, measuring from 0.4 cm to 1.3 cm in greatest dimension, and are grossly unremarkable. Labeled C1 to C3 - lymph nodes. Jar 1.

The fourth container is labeled "right peri-aortic lymph node." It contains multiple fragments of fibrofatty tissue measuring 2.5 x 2 x 0.6 cm in aggregate. Two putative lymph nodes are dissected out, measuring 1 x 0.3 and 1.2 x 0.4 x 0.2 cm. Labeled D1. Jar 0.

The fifth container is labeled "left peri-aortic lymph node." It contains one fragment of fibrofatty tissue measuring 0.7 x 0.2 cm. There is no lymph node found. Labeled E1. Jar 0.

The sixth container is labeled "left vaginal margin." It contains one fragment of grey-white and firm tissue measuring 0.6 x 0.4 cm. Labeled F1. Jar 0.

M.D., Ph.D.

Synopsis

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Squamous cell (epidermoid) carcinoma, invasive type
Keratinizing subtype
3. The MAXIMUM DEPTH OF TUMOR INVASION is 15 mm.
4. The BREADTH (MAXIMUM HORIZONTAL DIMENSION) OF THE TUMOR is 37 mm.
5. The TOTAL THICKNESS OF THE CERVIX is 17 mm.
6. Lymphatic invasion by tumor is identified and is WIDESPREAD.
7. The NUCLEAR GRADE of the tumor is:
2 (Moderately-differentiated)
8. The tumor DOES NOT invade through the entire thickness of the cervix to involve contiguous parametrium.
9. The tumor DOES involve the uterine lower segment.
10. The tumor DOES involve the vagina. Because invasive tumor is present in the separately submitted "left vaginal margin," the extent of vaginal involvement cannot be determined from pathologic information and clinical correlation.
11. Metastasis to regional lymph nodes is PRESENT.
12. The total number of metastatically-involved nodes is 2.
13. The total number of regional nodes examined is 19.
14. Extracapsular extension of metastatic tumor through the lymph node capsule is ABSENT.
15. DETAILED STAGING INFORMATION:

A. TUMOR GROWTH: THE PRIMARY NEOPLASM IS CLASSIFIED AS:

TNM SCHEME	FIGO SCHEME	DEFINITION
TX	N/A	Primary tumor cannot be evaluated because invasive tumor is the separately submitted specimen of "left vaginal margin" therefore the extent of vaginal involvement is unknown.

B. REGIONAL LYMPH NODES are classified as:

N1 (Regional nodes ARE involved by metastasis)

C. DISTANT METASTASES: The status of distant tissues is:

X (Status cannot be assessed)

16. THE FINAL STAGE OF THE TUMOR IS:

AJCC SCHEME

X

FIGO SCHEME

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of all available information.

Source: NCI Genomic Data Commons file cbbdcd1b-deea-484c-9bc1-03ca022893ba (TCGA-C5-A901.5190FB9E-E28B-4CAB-9FB1-9DF839F2D977.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).